Somatic mutation profile of tumor specimen TCGA-WJ-A86L-01A (aliquot TCGA-WJ-A86L-01A-12D-A45V-10) from TCGA case TCGA-WJ-A86L, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 68.5 years (25,018 days).
Specimen TCGA-WJ-A86L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 238733b9-34e2-4e91-a2a9-3b1dfc0527f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WJ-A86L-10A (Blood Derived Normal), aliquot TCGA-WJ-A86L-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc36e2bc-203c-4256-90aa-b97869cd7749

The open-access MAF lists 140 somatic variants for this specimen: 107 protein-altering or splice-affecting, 27 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 27, Frame Shift Del 8, Nonsense Mutation 7, 3'UTR 2, Intron 2, RNA 2, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AARD | c.366A>C p.L122F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV100991835; called by muse, mutect2, varscan2
- ABCB5 | c.1604T>G p.I535S (on ENST00000404938 / NM_001163941.2; = p.I90S on NM_178559.6) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51711466, COSV99327563; called by muse, mutect2, varscan2
- ABCC11 | c.2150G>A p.S717N | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62323397; called by muse, mutect2, varscan2
- ADAMTS16 | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99940261; called by muse, mutect2, varscan2
- AP3D1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs989616684, COSV61429376; called by muse, mutect2, varscan2
- APAF1 | c.3593A>G p.Y1198C (on ENST00000551964 / NM_181861.2; = p.Y1144C on NM_001160.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.874); catalogued as rs1271853699, COSV100452315; called by muse, mutect2, varscan2
- APLF | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 129/259 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV100376433; called by muse, mutect2, varscan2
- ARHGEF40 | c.4247C>T p.A1416V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100070061; called by muse, mutect2, varscan2
- ASL | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100508830; called by muse, mutect2, varscan2
- ATP6V0A1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 190/295 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs370052932, COSV99230542; called by muse, mutect2, varscan2
- BMP15 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 114/245 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99399207; called by muse, mutect2, varscan2
- C2CD5 | c.66T>G p.S22R | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100448512; called by muse, mutect2, varscan2
- C7orf33 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs142396932, COSV100188703; called by muse, mutect2
- CACNA1E | c.3892C>G p.L1298V | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100701378; called by muse, mutect2, varscan2
- CD1A | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV56860452, COSV56861432, COSV99192208; called by muse, mutect2, varscan2
- CD300LB | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100075328; called by muse, mutect2, varscan2
- CD6 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 54/107 reads (50%) | catalogued as COSV100532828; called by muse, mutect2, varscan2
- CDH10 | c.353A>T p.D118V | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050298; called by muse, mutect2, varscan2
- CDH15 | c.2036del p.S679Tfs*71 | Frame Shift Del (DEL) | VAF 26/43 reads (60%) | catalogued as COSV57024701; called by mutect2, pindel, varscan2
- CHST3 | c.796C>G p.R266G | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT tolerated (0.28); PolyPhen benign (0.293); catalogued as rs1041291103, COSV100910402; called by muse, mutect2, varscan2
- CMYA5 | c.7662G>T p.Q2554H | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.243); catalogued as rs1170574955, COSV101483891; called by muse, mutect2, varscan2
- CNGB3 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181367, COSV100182834; called by muse, mutect2, varscan2
- CTNNA1 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.042); catalogued as COSV100242247; called by muse, mutect2, varscan2
- CYLC2 | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs373184793; called by muse, mutect2, varscan2
- CYP4A11 | c.572T>C p.L191S | Missense Mutation (SNP) | VAF 145/344 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as COSV100152213; called by muse, mutect2, varscan2
- DACH2 | c.1587G>T p.L529F | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1291863750, COSV100912634; called by muse, mutect2, varscan2
- DCAF11 | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100386594; called by muse, mutect2, varscan2
- DDX60L | c.3202del p.Q1068Kfs*2 | Frame Shift Del (DEL) | VAF 29/87 reads (33%) | catalogued as COSV99488616; called by mutect2, pindel, varscan2
- DMKN | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as rs561680729, COSV100303264; called by muse, mutect2, varscan2
- DPP9 | c.568G>C p.D190H (on ENST00000598800; = p.D219H on NM_139159.5) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99505763; called by muse, mutect2, varscan2
- EPHA3 | c.2218A>T p.M740L | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.749); catalogued as rs762621864, COSV100343365; called by muse, mutect2, varscan2
- FAM162A | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99216275; called by muse, mutect2, varscan2
- FAM171B | c.1859G>A p.W620* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | catalogued as COSV100488315; called by muse, mutect2, varscan2
- FOXR2 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 69/129 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.1); catalogued as COSV100189347, COSV100189420; called by muse, mutect2, varscan2
- FRAS1 | c.9985G>A p.D3329N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1174411329, COSV53645560, COSV99348789; called by muse, mutect2, varscan2
- GABRG2 | c.1245C>G p.N415K (on ENST00000361925 / NM_001375343.1; = p.N375K on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.995); catalogued as COSV100729594, COSV62718248; called by muse, mutect2, varscan2
- GATA3 | c.895C>A p.P299T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774440409, COSV100650841; called by muse, mutect2, varscan2
- GPC6 | c.1658T>A p.L553Q | Missense Mutation (SNP) | VAF 31/34 reads (91%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100988125; called by muse, mutect2, varscan2
- GRIN3A | c.822G>A p.W274* | Nonsense Mutation (SNP) | VAF 7/147 reads (5%) | catalogued as rs1348195697, COSV100701386, COSV62456586; called by muse, mutect2
- HEPHL1 | c.2935C>G p.H979D | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100243584, COSV59894927; called by muse, mutect2, varscan2
- HNF1A | c.1502-1G>A p.X501_splice | Splice Site (SNP) | VAF 41/98 reads (42%) | catalogued as COSV99982193; called by muse, mutect2, varscan2
- INF2 | c.3341T>A p.L1114H | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV99383547; called by muse, mutect2, varscan2
- ITGA3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs140829923; called by muse, mutect2, varscan2
- ITGA4 | c.2192A>T p.D731V | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101223149; called by muse, mutect2, varscan2
- KIAA1841 | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.104); catalogued as COSV99693371; called by muse, mutect2, varscan2
- KRT78 | c.773A>C p.Q258P | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100467141; called by muse, mutect2, varscan2
- LMO4 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.638); catalogued as COSV100983967; called by muse, mutect2, varscan2
- LPCAT3 | c.127C>G p.R43G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99781488; called by muse, mutect2, varscan2
- MOCS1 | c.1132C>T p.R378W | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs149586823, COSV51418796; called by muse, mutect2, varscan2
- MS4A15 | c.517C>A p.L173M (on ENST00000405633 / NM_001098835.2; = p.L80M on NM_152717.3) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.996); catalogued as COSV100558840; called by muse, mutect2, varscan2
- MUC16 | c.22965G>T p.Q7655H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV101198410; called by muse, mutect2, varscan2
- MYO1E | c.1831G>A p.G611S | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99894606; called by muse, mutect2, varscan2
- NEK9 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463614; called by muse, mutect2, varscan2
- NOTCH3 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99656099; called by muse, mutect2, varscan2
- NPAS1 | c.1359C>A p.N453K | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV53409924, COSV99451334; called by muse, mutect2, varscan2
- OPN4 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747304015, COSV99618075; called by muse, mutect2, varscan2
- OR10Z1 | c.682A>G p.I228V | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs904696451, COSV100778948; called by muse, mutect2, varscan2
- OR2T4 | c.80A>C p.H27P | Missense Mutation (SNP) | VAF 87/343 reads (25%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100822406; called by muse, mutect2, varscan2
- OR52N1 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV57693871; called by muse, mutect2, varscan2
- PHIP | c.2756A>T p.E919V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0.225); catalogued as COSV99243518; called by muse, mutect2, varscan2
- PHIP | c.1085A>T p.E362V | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99243521; called by muse, mutect2, varscan2
- PIGW | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs886794381; called by muse, mutect2, varscan2
- PIKFYVE | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100009977; called by muse, mutect2, varscan2
- PKHD1L1 | c.1603C>A p.P535T | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs761631259, COSV101005519, COSV65748219; called by muse, mutect2, varscan2
- PKHD1L1 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.51); catalogued as COSV65748065, COSV65750348; called by muse, mutect2, varscan2
- PLD3 | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV99396404; called by muse, mutect2, varscan2
- PLXNA1 | c.2017G>T p.G673C | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99302422; called by muse, mutect2, varscan2
- PLXNA2 | c.2267A>G p.N756S | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV100885199; called by muse, mutect2, varscan2
- PNPO | c.427A>C p.K143Q (on ENST00000225573; = p.K186Q on NM_018129.4) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.114); catalogued as COSV99846462; called by muse, mutect2, varscan2
- POLR1F | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99748634; called by muse, mutect2, varscan2
- PREX2 | c.3533G>C p.G1178A | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV55775786, COSV55786310, COSV99905418; called by muse, mutect2, varscan2
- PXMP4 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs182672515, COSV99459289; called by muse, mutect2, varscan2
- QRFPR | c.1159A>G p.K387E | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV100543502; called by muse, mutect2, varscan2
- RANBP17 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101206114; called by muse, mutect2, varscan2
- RAPH1 | c.384G>T p.L128F | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV100051141; called by muse, mutect2, varscan2
- RBM42 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99177883; called by muse, mutect2, varscan2
- RPS6KC1 | c.1060G>A p.D354N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV65299471; called by muse, mutect2, varscan2
- RTN1 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99954786; called by muse, mutect2, varscan2
- SCUBE3 | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV99234021; called by muse, mutect2, varscan2
- SEL1L2 | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV53160407; called by muse, mutect2, varscan2
- SEMA7A | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as rs758202912, COSV56092546; called by muse, mutect2, varscan2
- SLC25A10 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100518946; called by muse, mutect2, varscan2
- SLCO1C1 | c.1850T>C p.L617P | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1450408967, COSV99858602; called by muse, mutect2, varscan2
- SRRM3 | c.175C>A p.R59S | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100418591; called by muse, mutect2, varscan2
- SYT7 | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs746777211, COSV99801192; called by muse, mutect2, varscan2
- TAF4B | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99299826; called by muse, mutect2, varscan2
- TBC1D4 | c.32C>G p.P11R | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.993); catalogued as COSV100884536; called by muse, mutect2, varscan2
- TBX20 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV68783409; called by muse, mutect2, varscan2
- THOC5 | c.1523A>G p.Q508R | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.255); catalogued as COSV100803469; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 47/58 reads (81%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRPM2 | c.2185T>C p.F729L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100308277; called by muse, mutect2, varscan2
- TTC38 | c.1174G>T p.D392Y | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101123856; called by muse, mutect2, varscan2
- USH2A | c.2428G>T p.A810S | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV100230057; called by muse, mutect2, varscan2
- ZIM3 | c.1264A>G p.S422G | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.215); catalogued as COSV99517757; called by muse, mutect2, varscan2
- ZNF232 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs966159418, COSV100005556; called by muse, mutect2, varscan2
- ZNF521 | c.526T>C p.C176R | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831527; called by muse, mutect2, varscan2
- ZNF578 | c.1371T>A p.C457* | Nonsense Mutation (SNP) | VAF 38/91 reads (42%) | catalogued as COSV101405016; called by muse, mutect2, varscan2
- ZNF774 | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV100586233; called by muse, mutect2, varscan2
- DDX31 | c.1863del p.I622Lfs*41 | Frame Shift Del (DEL) | VAF 32/68 reads (47%) | called by mutect2, pindel*, varscan2
- DLX5 | c.249del p.A84Pfs*39 | Frame Shift Del (DEL) | VAF 44/102 reads (43%) | called by mutect2, pindel*, varscan2
- GNPNAT1 | c.20del p.P7Lfs*35 | Frame Shift Del (DEL) | VAF 29/84 reads (35%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- PTCH1 | c.1758del p.M587Wfs*36 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- PUS7 | c.1897_1899del p.T633del | In Frame Del (DEL) | VAF 30/83 reads (36%) | called by mutect2, pindel, varscan2
- SLC9A1 | c.1557_1560del p.N519Kfs*12 | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | called by mutect2, pindel, varscan2
- SYNRG | c.372G>A p.Q124= | Splice Region (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- ZCCHC14 | c.774del p.L259Cfs*44 (on ENST00000268616; = p.L396Cfs*44 on NM_015144.3) | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- AQR | c.1980A>G p.K660= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV99333328; called by muse, mutect2, varscan2
- DCXR | c.702T>G p.T234= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100141710; called by muse, mutect2, varscan2
- DENND3 | c.897G>T p.T299= | Silent (SNP) | VAF 30/57 reads (53%) | catalogued as COSV99370418, COSV99370825; called by muse, mutect2, varscan2
- DHX34 | c.1521G>T p.S507= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV100169307; called by muse, mutect2, varscan2
- DLEC1 | c.156T>A p.S52= | Silent (SNP) | VAF 51/125 reads (41%) | catalogued as COSV100341631; called by muse, mutect2, varscan2
- EFTUD2 | c.1800G>A p.L600= | Silent (SNP) | VAF 53/165 reads (32%) | catalogued as COSV101274518; called by muse, mutect2, varscan2
- FNBP4 | c.1647A>G p.Q549= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as rs79878695, COSV99771462; called by muse, mutect2, varscan2
- FRAS1 | c.4807C>A p.R1603= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as COSV53655438, COSV99348786; called by muse, mutect2, varscan2
- HOXB5 | c.555C>T p.I185= | Silent (SNP) | VAF 72/113 reads (64%) | catalogued as COSV99494393; called by muse, mutect2, varscan2
- HSP90AA1 | c.6T>A p.P2= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as COSV99355058; called by muse, mutect2
- INSC | c.969C>T p.G323= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as rs765348692, COSV101088813, COSV65412682; called by muse, mutect2, varscan2
- KIAA1109 | c.6747T>C p.S2249= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99146073; called by muse, mutect2, varscan2
- KIAA1549 | c.4920C>T p.I1640= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs756943187, COSV54312018; called by muse, mutect2, varscan2
- KIAA2013 | c.618C>A p.I206= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100927114; called by muse, mutect2, varscan2
- KRT6A | c.822G>A p.V274= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as COSV100416752; called by muse, mutect2, varscan2
- KRT85 | c.819C>T p.D273= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV99225190; called by muse, mutect2, varscan2
- NFAT5 | c.3972C>T p.P1324= | Silent (SNP) | VAF 54/68 reads (79%) | catalogued as rs760113102, COSV100590512, COSV63033726; called by muse, mutect2, varscan2
- NIPA1 | c.660C>T p.N220= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs780423343, COSV100507750; called by muse, mutect2, varscan2
- OR8B8 | c.564T>C p.A188= | Silent (SNP) | VAF 63/132 reads (48%) | catalogued as COSV100044876; called by muse, mutect2, varscan2
- OXTR | c.1005C>T p.H335= | Silent (SNP) | VAF 43/110 reads (39%) | catalogued as COSV100373058; called by muse, mutect2, varscan2
- PCDHA6 | c.441G>A p.L147= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as rs1239720499, COSV100972143, COSV100972687; called by muse, mutect2, varscan2
- PCNX1 | c.4758C>T p.F1586= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99454357; called by muse, mutect2, varscan2
- PRMT5 | c.87A>T p.T29= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99362799; called by muse, mutect2, varscan2
- RSPH10B2 | c.477G>A p.V159= | Silent (SNP) | VAF 46/192 reads (24%) | called by mutect2, varscan2
- SLC26A9 | c.2265G>T p.G755= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100536033; called by muse, mutect2, varscan2
- TBC1D1 | c.3426G>A p.T1142= | Silent (SNP) | VAF 43/131 reads (33%) | catalogued as rs375379532; called by muse, mutect2, varscan2
- UGT1A9 | c.168T>C p.V56= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs762092554, COSV60831774; called by muse, mutect2, varscan2
- AL590867.2 | n.56A>G | RNA (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- ELK4 | c.1080+12G>T | Intron (SNP) | VAF 40/138 reads (29%) | catalogued as rs765720756, COSV99222254; called by muse, mutect2, varscan2
- NT5E | c.1360+416G>C | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- PDGFD | c.*1G>T | 3'UTR (SNP) | VAF 53/102 reads (52%) | catalogued as COSV100158068; called by muse, mutect2
- PHGDH | c.*7C>G | 3'UTR (SNP) | VAF 38/88 reads (43%) | catalogued as COSV101024683, COSV65569361; called by muse, mutect2, varscan2
- TUBB7P | n.209C>T | RNA (SNP) | VAF 48/87 reads (55%) | catalogued as rs1561097831; called by muse, mutect2, varscan2
